CCDI case PBCDZM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2d26896a-64da-4469-82d7-84787f5bbfe1

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,133 days).

Biospecimens (4 samples)
- Sample 0DPSN5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ55O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Samples 0DQFIZ, 0DQSTU (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
